Somatic mutation profile of tumor specimen TCGA-HF-7132-01A (aliquot TCGA-HF-7132-01A-11D-2053-08) from TCGA case TCGA-HF-7132, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G2.
Specimen TCGA-HF-7132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f703d1c-a7a4-4296-b64c-174994f401c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-7132-10A (Blood Derived Normal), aliquot TCGA-HF-7132-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/952132bc-8705-4e08-ad8f-c4f9642b1db0

The open-access MAF lists 1,440 somatic variants for this specimen: 1,101 protein-altering or splice-affecting, 311 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 734, Silent 311, Frame Shift Del 223, Frame Shift Ins 64, Nonsense Mutation 39, Splice Site 17, Intron 14, In Frame Del 12, Splice Region 11, RNA 5, 3'Flank 4, 3'UTR 3.

Variants (750 of 1,440; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CASR | c.108del p.L37Sfs*8 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as rs886041823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFTR | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs121908810, CM960282, COSV50088660; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 47/223 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs140656187, COSV57258562; called by muse, mutect2, varscan2
- FANCC | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as rs781542763, CS982190, COSV56657190; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 64/282 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 19/121 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 31/178 reads (17%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- GUSB | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs121918173, CM910197; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1966del p.L656Cfs*274 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs886042284; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MFSD8 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 38/175 reads (22%) | catalogued as rs749315686, CM091347, COSV56552768; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBAS | c.2950del p.I984Lfs*8 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs776797592; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NPC1 | c.2978del p.G993Efs*4 | Frame Shift Del (DEL) | VAF 23/143 reads (16%) | catalogued as rs775915490, CD053590, COSV99342140; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PEX12 | c.1_2del p.M1? | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs1555549923; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PHEX | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs866429868, CM971158, COSV65078245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- SPTBN2 | c.7109G>A p.R2370H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs145522851; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by mutect2, varscan2
- ABCA1 | c.5516G>A p.R1839H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs139363994; called by muse, mutect2, varscan2
- ABCA1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs755100870, COSV66063425; called by muse, mutect2, varscan2
- ABCA2 | c.6820C>T p.H2274Y (on ENST00000614293; = p.H2244Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55805749; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB4 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); catalogued as rs1037196284, COSV55933716; called by muse, mutect2, varscan2
- ABCC12 | c.2816T>C p.F939S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV60917547; called by muse, mutect2, varscan2
- ABCC8 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56856353; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1223A>C p.K408T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68344555; called by muse, mutect2, varscan2
- ABHD16A | c.1594-2A>G p.X532_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV101013223; called by muse, mutect2, varscan2
- ABITRAM | c.261+2T>C p.X87_splice | Splice Site (SNP) | VAF 46/185 reads (25%) | catalogued as rs556836038, COSV59829720; called by muse, mutect2, varscan2
- AC008397.2 | c.1895A>C p.E632A | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53209243; called by muse, mutect2
- AC008397.2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750056384, COSV99441681; called by muse, mutect2, varscan2
- ACBD4 | c.739G>T p.G247W (on ENST00000376955 / NM_001378111.1; = p.R250M on NM_024722.4) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV58853265; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACSL3 | c.131del p.F44Sfs*17 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as COSV62484662; called by mutect2, pindel, varscan2
- ACSS1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs143890712; called by muse, mutect2, varscan2
- ACTL6A | c.269del p.N90Mfs*47 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | catalogued as rs1560010257; called by mutect2, pindel, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD2 | c.1378G>A p.V460I (on ENST00000315906 / NM_001145400.2; = p.V542I on NM_139174.4) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.143); catalogued as rs369743783; called by muse, mutect2, varscan2
- ADAM15 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV55129325; called by muse, mutect2, varscan2
- ADAM17 | c.1597_1599del p.K533del | In Frame Del (DEL) | VAF 46/266 reads (17%) | catalogued as rs760760055; called by pindel, varscan2
- ADAMTS5 | c.1522T>C p.C508R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53184203; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- ADGRG2 | c.357A>G p.S119= (on ENST00000379869 / NM_001079858.3; = p.S116= on NM_005756.4) | Splice Region (SNP) | VAF 21/164 reads (13%) | catalogued as COSV61340888; called by muse, mutect2, varscan2
- ADGRL3 | c.1673A>G p.Q558R (on ENST00000506720 / NM_001322402.2; = p.Q490R on NM_015236.6) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as rs747498945, COSV72231717; called by muse, mutect2, varscan2
- ADGRL4 | c.1985del p.L662Yfs*28 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | catalogued as rs770040543; called by mutect2, pindel, varscan2
- ADRB1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV65168431; called by muse, mutect2, varscan2
- AEBP1 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757009902, COSV56256190, COSV56260647; called by muse, mutect2, varscan2
- AFAP1 | c.1717_1719del p.E573del | In Frame Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs1560149375; called by pindel, varscan2
- AFF4 | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV54798609; called by muse, mutect2
- AFTPH | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53221166; called by muse, mutect2, varscan2
- AGL | c.1678A>C p.S560R | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV54057447; called by muse, mutect2, varscan2
- AGO1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV64596308; called by muse, mutect2, varscan2
- AGO1 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs371456175; called by muse, mutect2, varscan2
- AKAP13 | c.7745A>G p.Q2582R (on ENST00000394518 / NM_007200.5; = p.Q2586R on NM_006738.6) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1291406623, COSV63467324; called by muse, mutect2
- AKAP6 | c.4697C>A p.S1566* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV55229446; called by muse, mutect2, varscan2
- AKT3 | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV55629778; called by muse, mutect2, varscan2
- AL592490.1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as rs750532210, COSV69427234; called by muse, mutect2, varscan2
- AL645922.1 | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV54962244; called by muse, mutect2, varscan2
- ALDH3B2 | c.1131G>T p.M377I | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62429193; called by muse, mutect2, varscan2
- ALDOC | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs1320951923, COSV52023906; called by muse, mutect2, varscan2
- ALOX12B | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 65/316 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.234); catalogued as rs367693196; called by muse, mutect2, varscan2
- ALPP | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766177947, COSV67397462; called by muse, mutect2, varscan2
- AMER2 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs755445946, COSV100766255, COSV63436953; called by muse, mutect2, varscan2
- AMIGO3 | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57539084; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKLE1 | c.983G>A p.R328H (on ENST00000394458; = p.R274H on NM_152363.6) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs762002502, COSV63921519; called by muse, mutect2, varscan2
- ANKRD50 | c.2581T>A p.L861M | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.571); catalogued as rs373595841; called by muse, mutect2, varscan2
- ANO3 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV56805536; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- AP3S1 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV57476806; called by muse, mutect2, varscan2
- APBB2 | c.1586G>A p.R529Q (on ENST00000295974 / NM_001166050.2; = p.R530Q on NM_004307.2) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1247150269, COSV55960611; called by muse, mutect2, varscan2
- AQP6 | c.515del p.P172Rfs*4 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as COSV100210264, COSV59646898; called by mutect2, pindel, varscan2
- AQP8 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV54847066; called by muse, mutect2, varscan2
- ARHGAP21 | c.1757T>A p.I586N | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.251); catalogued as COSV57610164; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ARHGAP35 | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as rs1178793173, COSV68335079; called by muse, mutect2, varscan2
- ARHGAP39 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52775082, COSV99432426; called by muse, mutect2, varscan2
- ARHGEF2 | c.104G>A p.R35H (on ENST00000361247 / NM_001162383.2; = p.R8H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1174401642, COSV58116154; called by muse, mutect2, varscan2
- ARHGEF40 | c.1616C>T p.T539M | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs143657914; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | catalogued as COSV61372705; called by pindel, varscan2
- ARID1B | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1282942992, COSV51657347; called by muse, mutect2, varscan2
- ARID2 | c.5272-1G>T p.X1758_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57597338, COSV57612847; called by muse, mutect2, varscan2
- ARMCX6 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV62680919; called by muse, mutect2, varscan2
- ART5 | c.679del p.H227Mfs*18 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs748137393; called by mutect2, pindel, varscan2
- ASGR1 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52649546; called by muse, mutect2, varscan2
- ASPM | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs780791970, COSV54136935, COSV54140446; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATF4 | c.406dup p.Q136Pfs*44 | Frame Shift Ins (INS) | VAF 35/299 reads (12%) | catalogued as rs770192882; called by mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP13A4 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs761826068, COSV55074210; called by muse, mutect2, varscan2
- ATP2B3 | c.2608G>T p.G870C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54859080; called by muse, mutect2, varscan2
- AVPR1A | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481652349, COSV54545684; called by muse, mutect2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs752427670; called by mutect2, varscan2
- BIRC3 | c.352A>T p.T118S | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV54819404; called by muse, mutect2, varscan2
- BRAT1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930716310; called by muse, mutect2
- BRCA2 | c.4013G>A p.G1338D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV66461101; called by muse, mutect2, varscan2
- BRD3 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs202198193, COSV57703765; called by muse, mutect2, varscan2
- BRIX1 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV59131956; called by muse, mutect2, varscan2
- BTAF1 | c.5039G>A p.S1680N | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56438463; called by muse, mutect2, varscan2
- BTBD7 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs143569452; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C19orf47 | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 21/172 reads (12%) | catalogued as COSV63510897; called by muse, mutect2, varscan2
- C2CD5 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV61727203; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 11/79 reads (14%) | catalogued as rs372345940; called by mutect2, varscan2
- CABIN1 | c.4819G>A p.V1607M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1199064856, COSV54088006; called by muse, mutect2, varscan2
- CACNA1B | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751354741, COSV53122440; called by muse, mutect2, varscan2
- CACNA1F | c.4807G>T p.G1603W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1557105753, COSV59906577; called by muse, mutect2, varscan2
- CACNA1G | c.6722G>A p.R2241Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs1264243708, COSV100661629, COSV61736405; called by muse, mutect2, varscan2
- CACUL1 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs867061045, COSV60994407; called by muse, mutect2
- CAD | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286557374, COSV53031022; called by muse, mutect2, varscan2
- CADPS | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51898604; called by muse, mutect2, varscan2
- CAMK1 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV56540171; called by muse, mutect2
- CAMSAP3 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV50352136; called by muse, varscan2
- CAND2 | c.3664_3666del p.K1222del (on ENST00000456430 / NM_001162499.2; = p.K1105del on NM_012298.3) | In Frame Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs774033982; called by mutect2, pindel, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs35832225; called by mutect2, varscan2
- CARNS1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757550437, COSV57053839; called by muse, mutect2, varscan2
- CAVIN2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs572661315, COSV58425011, COSV58425597; called by muse, mutect2, varscan2
- CC2D1A | c.2074-1G>T p.X692_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as COSV58785770; called by muse, mutect2, varscan2
- CCDC97 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV54190374, COSV54191488; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CD34 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60414724; called by muse, mutect2, varscan2
- CD9 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV50531333; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC14A | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV60562505; called by muse, varscan2
- CDC14A | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV60562524; called by muse, varscan2
- CDCA7L | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs766188645, COSV100178838, COSV60976129; called by muse, mutect2, varscan2
- CDH10 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as COSV52590904; called by muse, mutect2, varscan2
- CDH11 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs747102834, COSV51774410, COSV51776848, COSV99219561; called by muse, mutect2, varscan2
- CDH11 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339416150, COSV51752888, COSV51764246; called by muse, mutect2, varscan2
- CDH23 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368817860; called by muse, mutect2, varscan2
- CDKL5 | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs1370629084, COSV66112969; called by muse, mutect2, varscan2
- CEL | c.82G>A p.A28T (on ENST00000673714; = p.A25T on NM_001807.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs779607772, COSV60829288; called by muse, mutect2, varscan2
- CELSR1 | c.7595C>T p.T2532I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs542670900, COSV53098222; called by muse, mutect2, varscan2
- CELSR3 | c.7296-2A>G p.X2432_splice | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99373500; called by muse, mutect2, varscan2
- CELSR3 | c.2555A>G p.N852S | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51136774; called by muse, mutect2, varscan2
- CELSR3 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51136837; called by muse, mutect2, varscan2
- CENPK | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54469397; called by muse, mutect2
- CEP170 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs754809055; called by muse, mutect2
- CEP192 | c.4577C>T p.T1526M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867054939, COSV58069586; called by muse, mutect2, varscan2
- CFAP251 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.43); catalogued as COSV56614849; called by muse, mutect2, varscan2
- CFAP65 | c.4041T>A p.N1347K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779067104, COSV58565599; called by muse, varscan2
- CGB7 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.83); PolyPhen probably damaging (0.995); catalogued as COSV62282393; called by muse, mutect2, varscan2
- CHD3 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57879385; called by muse, mutect2, varscan2
- CHD7 | c.7222G>A p.E2408K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as rs1341064149, COSV71113851; called by muse, mutect2
- CHD9 | c.6934G>A p.D2312N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV54615328; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRM2 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as COSV57782329; called by muse, mutect2, varscan2
- CHST1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as rs763733732, COSV57321916, COSV57325297; called by muse, mutect2, varscan2
- CHST15 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs774519865, COSV60565153; called by muse, mutect2, varscan2
- CHURC1 | c.286G>C p.A96P (on ENST00000549115 / NM_001204063.1; = p.A97P on NM_145165.3) | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63036639; called by muse, mutect2, varscan2
- CIT | c.4004C>T p.P1335L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs779515686, COSV55877714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCA1 | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs570837989, COSV52330560; called by muse, mutect2, varscan2
- CLIP4 | c.1819A>G p.S607G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs200138252, COSV60751998; called by muse, mutect2, varscan2
- CLPTM1 | c.586+1G>T p.X196_splice | Splice Site (SNP) | VAF 21/118 reads (18%) | catalogued as rs111806238, COSV61612835; called by muse, mutect2, varscan2
- CLSTN1 | c.2362C>T p.R788W (on ENST00000377298 / NM_001009566.3; = p.R778W on NM_014944.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1270731621, COSV100790796, COSV63650552; called by muse, mutect2, varscan2
- CMYA5 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV71409007; called by muse, mutect2, varscan2
- CMYA5 | c.6876del p.E2293Kfs*9 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs745742163; called by mutect2, pindel, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | catalogued as rs753922055; called by mutect2, varscan2
- CNOT7 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV63518336; called by muse, mutect2
- CNTRL | c.1336del p.I446* | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs747099268; called by mutect2, varscan2
- COL12A1 | c.5957C>T p.T1986M | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs768824483, COSV59405624; called by muse, mutect2, varscan2
- COL12A1 | c.5771G>A p.R1924H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs751986784, COSV100486301, COSV59395186; called by muse, mutect2, varscan2
- COL12A1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs575168916, COSV59396982; called by muse, mutect2, varscan2
- COL22A1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57355936; called by muse, mutect2
- COL4A2 | c.4952G>T p.R1651L | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64633022; called by muse, mutect2, varscan2
- COL6A2 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56014317; called by muse, mutect2, varscan2
- COL7A1 | c.7657C>T p.R2553W | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs752294739, COSV60401897; called by muse, mutect2, varscan2
- COX6B1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV55838410; called by muse, mutect2, varscan2
- CPAMD8 | c.1807del p.G604Vfs*33 (on ENST00000651564; = p.G557Vfs*33 on NM_015692.5) | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV52236853; called by mutect2, pindel
- CPT1A | c.2236-1G>T p.X746_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99681146; called by muse, mutect2
- CR1 | c.5353C>T p.H1785Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV65462285; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 39/228 reads (17%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRAMP1 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1261501449, COSV51961862; called by muse, mutect2, varscan2
- CREBBP | c.7285G>A p.D2429N | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV52132851, COSV52137880; called by muse, mutect2, varscan2
- CRMP1 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV61482577; called by muse, mutect2, varscan2
- CSDE1 | c.2294C>T p.A765V (on ENST00000358528 / NM_001007553.3; = p.A734V on NM_007158.6) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as COSV54757518; called by muse, mutect2, varscan2
- CSF2RB | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV53260518; called by muse, mutect2, varscan2
- CSMD1 | c.2770T>G p.L924V (on ENST00000520002; = p.L923V on NM_033225.6) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59372220; called by muse, mutect2
- CSNK1G3 | c.145del p.I49Lfs*11 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs775129818, COSV62054115, COSV62057434; called by mutect2, varscan2
- CTNNA2 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV63595516; called by muse, mutect2, varscan2
- CXCL2 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56022041; called by muse, mutect2, varscan2
- CXCR6 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs771676006, COSV56115534; called by muse, mutect2, varscan2
- CYB561D2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV51601581; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP26A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56419706; called by muse, mutect2, varscan2
- CYP2A6 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV56536923; called by muse, mutect2, varscan2
- DAB2IP | c.3439C>T p.R1147C (on ENST00000408936; = p.R1119C on NM_032552.3) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52260687; called by muse, mutect2, varscan2
- DCAF4L1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753214088, COSV60786823; called by muse, mutect2, varscan2
- DCLK3 | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69364447; called by muse, mutect2, varscan2
- DDB1 | c.2782C>T p.R928C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57105207; called by muse, mutect2, varscan2
- DEPDC1 | c.1920G>T p.M640I (on ENST00000456315 / NM_001114120.3; = p.M356I on NM_017779.6) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV63959103; called by muse, mutect2, varscan2
- DEPDC1 | c.1021T>A p.S341T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV63959112; called by muse, mutect2, varscan2
- DGCR2 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV54221151; called by muse, mutect2
- DHX38 | c.407_408del p.E136Afs*29 | Frame Shift Del (DEL) | VAF 26/189 reads (14%) | catalogued as rs1376393495; called by pindel, varscan2
- DICER1 | c.2439T>C p.I813= | Splice Region (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58626530; called by muse, mutect2, varscan2
- DICER1 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV58626544; called by muse, mutect2, varscan2
- DIS3L2 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1386953024, COSV56061787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG5 | c.3998C>T p.A1333V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs920117413, COSV64949553; called by muse, mutect2, varscan2
- DLGAP2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.624); catalogued as COSV70103236; called by muse, mutect2
- DLX2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as COSV52232761; called by muse, mutect2, varscan2
- DLX3 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV71547895; called by muse, mutect2, varscan2
- DMD | c.5437A>G p.N1813D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.268); catalogued as CD066356, COSV63785077; called by muse, mutect2, varscan2
- DNAH17 | c.10954C>T p.R3652C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs749125075, COSV67753741; called by muse, mutect2, varscan2
- DNAH17 | c.9392C>T p.P3131L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs1003185850, COSV67760139; called by muse, mutect2
- DNAH17 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as COSV101102294; called by muse, mutect2
- DNAH3 | c.9353C>T p.A3118V | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs148895333; called by muse, mutect2, varscan2
- DNAH3 | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201134468, COSV54517912; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs1176934751, COSV59474807; called by muse, mutect2, varscan2
- DNAI3 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as rs145459682; called by muse, mutect2, varscan2
- DNAJC21 | c.1648G>T p.G550C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57762298; called by muse, mutect2, varscan2
- DNER | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59174477; called by muse, mutect2, varscan2
- DNMBP | c.3838C>A p.L1280I | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV60625296; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.5474C>T p.S1825L (on ENST00000376460 / NM_001366676.2; = p.S1826L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs532217839, COSV59641018; called by muse, mutect2, varscan2
- DOK5 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV52815994, COSV52824312; called by muse, mutect2, varscan2
- DOP1B | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs762995201, COSV67695602; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs750520568; called by mutect2, pindel
- DPP3 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs202120263, COSV64757828; called by muse, mutect2, varscan2
- DPP6 | c.1183G>A p.A395T (on ENST00000377770 / NM_001364500.2; = p.A333T on NM_001936.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs373224292, COSV100125862; called by muse, mutect2, varscan2
- DPPA2 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.374); catalogued as COSV72118285; called by muse, mutect2, varscan2
- DPPA3 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1384240409, COSV61503509; called by muse, mutect2, varscan2
- DRG2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV52763980; called by muse, varscan2
- DSCAML1 | c.5312A>G p.Q1771R (on ENST00000321322; = p.Q1711R on NM_020693.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs779073581, COSV58400899; called by muse, mutect2, varscan2
- DTNB | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs1319182856, COSV56483137; called by muse, mutect2, varscan2
- DUSP22 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147274051, COSV60530589; called by muse, mutect2
- DYNC1H1 | c.8779C>T p.R2927C | Missense Mutation (SNP) | VAF 65/396 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64136696; called by muse, mutect2, varscan2
- DYRK1A | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs758727805, COSV58298170; called by muse, mutect2, varscan2
- DYRK1A | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV58296270, COSV58296621; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- DYTN | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV101510830; called by muse, mutect2, varscan2
- E2F7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754738203, COSV59738194; called by muse, mutect2, varscan2
- EBF2 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375806937; called by muse, mutect2
- EEA1 | c.4111C>T p.R1371W | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs560597630, COSV59289251; called by muse, mutect2
- EFNA1 | c.168T>A p.D56E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV100310333; called by muse, mutect2, varscan2
- EGFLAM | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs761321149, COSV59314558, COSV99054987; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs886039350; ClinVar: uncertain significance; called by pindel, varscan2
- ELFN2 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68746217; called by muse, mutect2, varscan2
- ELFN2 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764581745, COSV101297626, COSV68744379; called by muse, mutect2, varscan2
- ELL2 | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV52984753; called by muse, mutect2, varscan2
- ELMO1 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209023342, COSV60300078, COSV60300321; called by muse, mutect2, varscan2
- ELOVL6 | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV56431653; called by muse, mutect2, varscan2
- ENDOU | c.685G>A p.A229T (on ENST00000422538 / NM_001172439.2; = p.A188T on NM_006025.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs753275788, COSV57465906; called by muse, mutect2, varscan2
- ENPP3 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767163918, COSV62956170; called by muse, mutect2, varscan2
- EPHA10 | c.2711T>C p.V904A | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57626749; called by muse, mutect2
- EPHA10 | c.1494T>C p.G498= | Splice Region (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100360810, COSV57626757; called by muse, mutect2, varscan2
- EPHB1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV67654484; called by muse, mutect2, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs1394740497; called by mutect2, pindel, varscan2
- ERBB3 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.351); catalogued as rs777498890, COSV57261425; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT2 | c.1078G>A p.V360M (on ENST00000613624; = p.V284M on NM_020728.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51755511; called by muse, mutect2, varscan2
- EVPL | c.5270G>A p.R1757H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1315113869, COSV56914909; called by muse, mutect2, varscan2
- EVPL | c.4039G>A p.A1347T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1567907456, COSV56906602; called by muse, mutect2, varscan2
- EXOC8 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV50479341; called by muse, mutect2, varscan2
- EXT1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV65483992; called by muse, mutect2, varscan2
- F8 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV64277788; called by muse, varscan2
- FAM114A1 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV62674556; called by muse, mutect2, varscan2
- FAM171A1 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65319295; called by muse, mutect2, varscan2
- FAM193A | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); catalogued as rs770334968, COSV61193554; called by muse, mutect2
- FAM214A | c.2998C>T p.Q1000* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as rs1350051952, COSV55926754; called by muse, mutect2
- FAM91A1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 8/245 reads (3%) | catalogued as COSV58239138; called by muse, mutect2
- FAM91A1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs569914662, COSV100593579; called by muse, mutect2, varscan2
- FAM98A | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV53211617; called by muse, mutect2, varscan2
- FAT2 | c.9955C>T p.P3319S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55827764; called by muse, mutect2
- FAT3 | c.9407A>G p.Y3136C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as rs983818132, COSV53162771; called by muse, mutect2, varscan2
- FAT3 | c.11393C>A p.P3798H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.758); catalogued as COSV53162837; called by muse, mutect2, varscan2
- FAT4 | c.10396G>A p.V3466I | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as rs373744467; called by muse, mutect2, varscan2
- FCRL3 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV63844383; called by muse, mutect2, varscan2
- FES | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs771148515, COSV61000563; called by mutect2, varscan2
- FGF3 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs150581924, COSV61925255; called by muse, mutect2, varscan2
- FLG | c.8569C>T p.R2857C | Missense Mutation (SNP) | VAF 84/466 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as rs762486668, COSV100910389, COSV64247348; called by muse, varscan2
- FLT1 | c.2869C>A p.L957I | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as COSV56739725; called by muse, mutect2
- FLT4 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1489676984, COSV56099983, COSV56119456; called by muse, mutect2, varscan2
- FNDC3B | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs754538002, COSV61037387; called by muse, mutect2, varscan2
- FOXA3 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as rs1160281424, COSV100141383; called by muse, mutect2, varscan2
- FOXH1 | c.937del p.V313Wfs*15 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | catalogued as COSV56761013; called by mutect2, pindel, varscan2
- FOXP1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV59552344; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRY | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66577738; called by muse, mutect2
- FRYL | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1434247426, COSV51959281; called by muse, mutect2, varscan2
- FUT5 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs745747279, COSV53138351; called by muse, mutect2, varscan2
- FUT6 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV54607901; called by muse, mutect2, varscan2
- FZD10 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV57475471; called by muse, mutect2, varscan2
- GAA | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs150868652, CM152916; ClinVar: uncertain significance; called by muse, varscan2
- GABRG1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); catalogued as rs1281060244, COSV54951753, COSV54960307; called by muse, mutect2, varscan2
- GAS7 | c.821C>T p.A274V (on ENST00000432992 / NM_201433.2; = p.A134V on NM_003644.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs769045182, COSV60442422; called by muse, mutect2, varscan2
- GCN1 | c.4895G>A p.R1632Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56113675; called by muse, mutect2, varscan2
- GGA1 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs768342061, COSV57329910; called by muse, mutect2, varscan2
- GGA3 | c.707G>A p.S236N (on ENST00000537686 / NM_138619.4; = p.S203N on NM_014001.5) | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV55458587; called by muse, varscan2
- GIPR | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as rs199991013, COSV54425732; called by muse, mutect2, varscan2
- GLI3 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as rs1481839480, CD050878, COSV67894030; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAL | c.862G>A p.V288I (on ENST00000269162 / NM_001142339.3; = p.V365I on NM_182978.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV52332860; called by muse, mutect2, varscan2
- GNAS | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1358580640, COSV58329649; called by muse, mutect2
- GNL3 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56478484; called by mutect2, varscan2
- GOLGB1 | c.3291G>A p.M1097I | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61470010; called by muse, mutect2, varscan2
- GPAM | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62082374; called by muse, mutect2, varscan2
- GPBAR1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50309369; called by muse, mutect2, varscan2
- GPER1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as COSV52470401; called by muse, mutect2, varscan2
- GPR82 | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV56888152; called by muse, mutect2, varscan2
- GPRASP2 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs375571887, COSV59990483; called by muse, mutect2, varscan2
- GRB10 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1471697984, COSV60015522; called by muse, mutect2
- GREB1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52189489; called by muse, mutect2, varscan2
- GRIA2 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV52403065, COSV99645583; called by muse, mutect2, varscan2
- GRIP1 | c.1963C>T p.R655C (on ENST00000359742 / NM_001379345.1; = p.R603C on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs201662071, COSV54028939; called by muse, mutect2, varscan2
- GRK6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); catalogued as rs1464315015, COSV62684077; called by muse, mutect2, varscan2
- HACL1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs759979137, COSV58256362; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HBQ1 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52265985; called by muse, mutect2, varscan2
- HDGF | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 143/532 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV61977607; called by muse, mutect2, varscan2
- HEG1 | c.2810A>G p.Y937C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60765016; called by muse, mutect2, varscan2
- HELQ | c.1320del p.G441Dfs*5 | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | catalogued as COSV55025197; called by mutect2, pindel, varscan2
- HERC4 | c.2771G>A p.C924Y (on ENST00000395198 / NM_022079.3; = p.C916Y on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53274538; called by muse, mutect2, varscan2
- HEXD | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201473179, COSV60063259; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 95/317 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2, varscan2
- HFM1 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); catalogued as COSV54035561; called by muse, mutect2, varscan2
- HHAT | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs751737702, COSV54807620, COSV99802836, COSV99805987; called by muse, varscan2
- HIPK4 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV52524957; called by muse, mutect2, varscan2
- HK3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs781200940, COSV52837709; called by muse, mutect2, varscan2
- HMBS | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV53829900; called by muse, mutect2, varscan2
- HMCN1 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933611; called by muse, mutect2, varscan2
- HMGXB4 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs1238177532, COSV53335721; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1940del p.G647Efs*268 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs1451726686; called by mutect2, pindel, varscan2
- HOATZ | c.62del p.P21Rfs*79 | Frame Shift Del (DEL) | VAF 8/97 reads (8%) | catalogued as rs570525399; called by mutect2, pindel
- HOXB13 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750244360, COSV51704993; ClinVar: uncertain significance; called by muse, varscan2
- HOXB13 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1467916908, COSV51704205, COSV99284840; ClinVar: uncertain significance; called by muse, varscan2
- HS3ST2 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs935612566, COSV54462873; called by muse, mutect2, varscan2
- HTR1E | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100541010, COSV59510472; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs748579647; called by mutect2, pindel
- HYDIN | c.10077dup p.L3360Afs*6 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | catalogued as rs781576725; called by mutect2, varscan2
- IFRD1 | c.1264A>C p.R422= | Splice Region (SNP) | VAF 9/67 reads (13%) | catalogued as COSV50045083; called by muse, mutect2, varscan2
- IFT80 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs147955112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGFN1 | c.1418C>T p.A473V (on ENST00000295591 / NM_001367841.1; = p.A2930V on NM_001164586.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV99812249; called by muse, mutect2, varscan2
- IGHV3-48 | c.42A>T p.L14F | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.07); catalogued as rs782745015; called by muse, mutect2, varscan2
- IGLV4-60 | c.346T>C p.W116R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV101135220; called by mutect2, varscan2
- IKBIP | c.626del p.N209Ifs*3 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs752553685; called by mutect2, varscan2
- IKBKB | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV60599408; called by muse, mutect2, varscan2
- IKBKE | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65626771; called by muse, mutect2, varscan2
- IL17RC | c.1099G>A p.A367T (on ENST00000295981 / NM_153461.4; = p.A281T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776089912, COSV55974769; called by muse, mutect2, varscan2
- IL23R | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV61375969; called by muse, mutect2, varscan2
- IL2RG | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52149994; called by muse, mutect2, varscan2
- IMPDH1 | c.797G>A p.G266D (on ENST00000470772 / NM_001142573.2; = p.G352D on NM_000883.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58317731; called by muse, mutect2, varscan2
- IMPDH2 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV58708875; called by muse, mutect2
- INF2 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs753323267, COSV53035926; called by muse, mutect2, varscan2
- INHBC | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV59005989; called by muse, mutect2, varscan2
- INO80 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV62740828; called by muse, varscan2
- INO80B | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs768723005, COSV51971376; called by muse, mutect2, varscan2
- INTS1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs768590543, COSV67179355; called by muse, mutect2, varscan2
- IQSEC1 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56228179; called by muse, mutect2, varscan2
- IQUB | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs991191779, COSV61239729, COSV61240279; called by muse, mutect2, varscan2
- IRS1 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100524498; called by mutect2, varscan2
- ISG20L2 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208445034, COSV57461187; called by muse, mutect2, varscan2
- ISL1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57935377; called by muse, mutect2
- ITGA7 | c.3444G>T p.W1148C (on ENST00000555728; = p.W1104C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57700019; called by muse, mutect2, varscan2
- ITGAX | c.2292C>T p.S764= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as rs1460191934, COSV51650504; called by muse, mutect2, varscan2
- ITGB5 | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.338); catalogued as COSV56152376; called by muse, varscan2
- ITPR1 | c.7936G>A p.V2646I (on ENST00000354582; = p.V2591I on NM_002222.7) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs568805900, COSV56999999; called by muse, mutect2
- ITPR3 | c.3080G>A p.R1027H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1314552852, COSV65413994; called by muse, mutect2, varscan2
- ITPR3 | c.6785G>A p.R2262H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs776633313, COSV65413059; called by muse, mutect2, varscan2
- JAK1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61095588; called by muse, mutect2
- JCAD | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV64758158, COSV64759952; called by muse, mutect2, varscan2
- JKAMP | c.490G>A p.V164I (on ENST00000554271 / NM_001284201.1; = p.V150I on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs1172897724, COSV54201145; called by muse, mutect2, varscan2
- KALRN | c.4198C>T p.R1400W | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775145320, COSV53756060, COSV53780259, COSV99565542; called by muse, mutect2, varscan2
- KCNA5 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52908149; called by muse, mutect2, varscan2
- KCND2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV58599457; called by muse, mutect2, varscan2
- KCNH1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55087341; called by muse, mutect2, varscan2
- KCNH7 | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59792242, COSV59807337; called by muse, mutect2, varscan2
- KCNJ5 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57966866; called by muse, mutect2
- KCNK5 | c.115T>C p.Y39H | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63989296; called by muse, mutect2, varscan2
- KCNQ2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60438552, COSV60439435; called by muse, mutect2
- KCNQ5 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541012691, COSV59678777; called by muse, mutect2, varscan2
- KCTD2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59369508; called by muse, mutect2, varscan2
- KCTD3 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.086); catalogued as COSV52069831; called by muse, mutect2
- KHDRBS2 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs776278021, COSV55485498; called by muse, mutect2, varscan2
- KIAA0895L | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs761836265, COSV51783947; called by muse, mutect2, varscan2
- KIN | c.505del p.T169Lfs*9 | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | catalogued as rs769387138, COSV65430366; called by mutect2, pindel
- KIR3DL2 | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54389382; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 56/152 reads (37%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLB | c.2605dup p.V869Gfs*32 | Frame Shift Ins (INS) | VAF 23/145 reads (16%) | catalogued as rs34101901; called by mutect2, pindel, varscan2
- KLF15 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1560036365, COSV56179099, COSV56179630; called by muse, mutect2
- KLF3 | c.546A>G p.V182= | Splice Region (SNP) | VAF 4/34 reads (12%) | catalogued as rs1156376462, COSV54712251; called by muse, mutect2
- KLF3 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1185801175, COSV54712265; called by muse, mutect2, varscan2
- KLHDC7A | c.2230A>G p.R744G | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV68770766; called by muse, mutect2, varscan2
- KLHDC9 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV63510474; called by muse, mutect2, varscan2
- KLHL12 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as rs1324971606, COSV66126161; called by muse, mutect2
- KLHL38 | c.248dup p.T84Nfs*19 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | catalogued as rs769840176; called by mutect2, pindel, varscan2
- KLK15 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56828361; called by mutect2, varscan2
- KMT2A | c.4778G>A p.R1593H | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.255); catalogued as rs782281385, COSV63291380; called by muse, mutect2, varscan2
- KMT2E | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV57578647, COSV57579742; called by muse, mutect2, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs761148574; called by mutect2, varscan2
- KRT34 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs201451902; called by muse, mutect2, varscan2
- KRT39 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 50/186 reads (27%) | catalogued as rs760470392, COSV62917042; called by muse, mutect2
- KRT76 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60121720; called by muse, mutect2, varscan2
- KRTAP10-1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV59976680; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV59960905; called by muse, mutect2, varscan2
- KRTAP27-1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV67001559; called by muse, mutect2, varscan2
- KRTAP5-1 | c.374del p.G125Dfs*? | Frame Shift Del (DEL) | VAF 31/163 reads (19%) | catalogued as COSV101192917; called by mutect2, pindel, varscan2
- KRTAP5-10 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | PolyPhen benign (0.015); catalogued as COSV64795816; called by muse, mutect2, varscan2
- KRTAP9-2 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.875); catalogued as COSV66647036; called by muse, mutect2, varscan2
- L3HYPDH | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55967708; called by muse, mutect2, varscan2
- LAIR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs758156418; called by muse, varscan2
- LAMA4 | c.1200_1202del p.N400del (on ENST00000230538 / NM_001105206.3; = p.N393del on NM_002290.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs1449255088; called by pindel, varscan2
- LAMP3 | c.761T>G p.V254G | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV55616672; called by muse, mutect2, varscan2
- LARP1 | c.2546+2T>C p.X849_splice (on ENST00000518297 / NM_033551.3; = p.X772_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/119 reads (19%) | catalogued as COSV60424749, COSV60430616; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LCA5 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63972768; called by muse, mutect2, varscan2
- LDLR | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs745343524, CM002351, CM014577, CM920453, COSV52945530; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LEPR | c.2913G>T p.E971D | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV62751060; called by muse, mutect2, varscan2
- LETM2 | c.1153C>A p.L385M (on ENST00000379957 / NM_001286819.2; = p.L290M on NM_144652.3) | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV52686651, COSV52687757; called by muse, mutect2, varscan2
- LEXM | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV64023981; called by muse, mutect2, varscan2
- LGALS9B | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60865789; called by muse, mutect2, varscan2
- LHX5 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV55662504; called by muse, mutect2, varscan2
- LIN7C | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1305337388, COSV53416458; called by muse, mutect2, varscan2
- LLGL1 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs751735771, COSV100375187, COSV57497034; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMOD2 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752055839, COSV71755586; called by muse, mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as rs762083435; called by mutect2, varscan2
- LRP1B | c.8264T>C p.I2755T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.272); catalogued as rs1404373878, COSV67264736; called by muse, mutect2, varscan2
- LRP2 | c.3671C>T p.T1224I | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55569996; called by muse, mutect2, varscan2
- LRP4 | c.5301_5302insA p.S1768Ifs*12 | Frame Shift Ins (INS) | VAF 25/117 reads (21%) | catalogued as COSV101066608; called by mutect2, pindel, varscan2
- LRP5 | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs373750800; called by muse, mutect2
- LRP5L | n.752G>T | Splice Region (SNP) | VAF 16/62 reads (26%) | catalogued as COSV68601988, COSV68602401; called by muse, mutect2, varscan2
- LRP8 | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60100778; called by muse, mutect2, varscan2
- LRRC25 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs551461923, COSV53251649; called by muse, mutect2, varscan2
- LRRC43 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs778932116, COSV60292788; called by muse, mutect2, varscan2
- LRRTM1 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.772); catalogued as rs540113878, COSV54445793, COSV99701744; called by muse, varscan2
- LSS | c.1527dup p.H510Afs*18 | Frame Shift Ins (INS) | VAF 11/97 reads (11%) | catalogued as rs1335748816; called by mutect2, pindel, varscan2
- LTBP3 | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57243533; called by muse, mutect2, varscan2
- LTV1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62536713; called by muse, mutect2, varscan2
- LYAR | c.230G>T p.W77L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV58642118, COSV58643848; called by muse, mutect2, varscan2
- LYSMD3 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100270339, COSV60058105; called by muse, mutect2, varscan2
- LZTS1 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1246539826, COSV56116486; called by muse, mutect2, varscan2
- MAD1L1 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV56245530; called by mutect2, varscan2
- MAGED1 | c.1883dup p.E629Gfs*3 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | catalogued as rs1557364762; called by mutect2, pindel, varscan2
- MAGEH1 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as rs1364018841, COSV61679157; called by muse, mutect2, varscan2
- MAGI2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV62691714; called by muse, mutect2, varscan2
- MAL | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV59432442; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP2K4 | c.429del p.K143Nfs*9 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV62254718; called by mutect2, pindel
- MAPK4 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752206576, COSV68543524; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MATN4 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | PolyPhen probably damaging (0.999); catalogued as rs747244790, COSV59215472; called by muse, mutect2, varscan2
- MBLAC1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs753136685, COSV53543214, COSV99498920; called by muse, mutect2, varscan2
- MCF2L | c.2804C>T p.A935V (on ENST00000375608; = p.A903V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as rs779688395, COSV56180736; called by muse, mutect2, varscan2
- MCM8 | c.1645A>G p.S549G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV54518039; called by muse, mutect2, varscan2
- MEIS3 | c.448-3dup | Splice Region (INS) | VAF 16/82 reads (20%) | catalogued as rs754589852; called by mutect2, varscan2
- MFN1 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1358058151, COSV54941991; called by muse, mutect2, varscan2
- MFSD6 | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV55624798; called by muse, mutect2
- MGRN1 | c.142del p.H48Tfs*13 | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | catalogued as COSV52148537; called by mutect2, pindel, varscan2
- MKI67 | c.2866C>T p.Q956* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV64076397; called by muse, mutect2, varscan2
- MLLT10 | c.1558_1560del p.P520del | In Frame Del (DEL) | VAF 13/72 reads (18%) | catalogued as rs759995798; called by mutect2, pindel, varscan2
- MLYCD | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs200365808; called by muse, mutect2, varscan2
- MMAB | c.290+2T>C p.X97_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV57170993; called by muse, mutect2, varscan2
- MMP16 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54175372; called by muse, mutect2
- MMP9 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); catalogued as rs1179114145, COSV63433987; called by muse, mutect2, varscan2
- MMRN2 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764051825, COSV100922446, COSV64401261; called by muse, mutect2
- MN1 | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56561394; called by muse, mutect2, varscan2
- MOV10L1 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV53177893; called by muse, mutect2, varscan2
- MPI | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60397509; called by muse, mutect2, varscan2
- MRPS31 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs1388979137, COSV60268495; called by muse, mutect2
- MSL2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV53866838; called by muse, mutect2, varscan2
- MTA1 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs782366619, COSV58759944; called by muse, mutect2
- MTBP | c.2071T>C p.C691R | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100012134; called by muse, mutect2, varscan2
- MTCL1 | c.3607G>A p.A1203T (on ENST00000306329 / NM_001378206.1; = p.A884T on NM_015210.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs745312691, COSV60406510; called by muse, mutect2, varscan2
- MUC16 | c.37855C>T p.R12619C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as rs765697877, COSV67444013; called by muse, mutect2, varscan2
- MUC20 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs770724904, COSV57854030; called by muse, mutect2, varscan2
- MUC5AC | c.14090G>A p.R4697H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.22); catalogued as rs200307483; called by muse, mutect2, varscan2
- MUC5B | c.14552C>T p.P4851L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs201730803; called by muse, mutect2
- MUC5B | c.15589G>A p.V5197I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs749312348, COSV71589870; called by muse, mutect2, varscan2
- MYBPC2 | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV63099201; called by muse, mutect2, varscan2
- MYH11 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs376622843; called by muse, mutect2, varscan2
- MYH13 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs377063691; called by muse, mutect2, varscan2
- MYH15 | c.2645G>T p.R882M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56317901; called by muse, mutect2, varscan2
- MYH3 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV56869155; called by muse, mutect2, varscan2
- MYLK | c.5558G>A p.R1853H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375758782; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 23/89 reads (26%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- MYO1B | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs147751540, COSV100268829; called by muse, mutect2, varscan2
- MYO1D | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as rs753254863, COSV59021781; called by muse, mutect2, varscan2
- MYO3B | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758246527, COSV58714690; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 24/111 reads (22%) | catalogued as rs769274302; called by mutect2, varscan2
- NADK2 | c.559C>T p.R187W (on ENST00000381937 / NM_001085411.3; = p.R24W on NM_153013.4) | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773035471, COSV56934989; called by muse, mutect2, varscan2
- NALCN | c.4739T>C p.L1580P | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51959748; called by muse, mutect2, varscan2
- NAV1 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55224499; called by muse, mutect2, varscan2
- NAV1 | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769287371, COSV55217104, COSV55222964; called by muse, mutect2, varscan2
- NAV3 | c.6508C>T p.H2170Y (on ENST00000397909 / NM_001024383.2; = p.H2148Y on NM_014903.6) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV57106771; called by muse, mutect2, varscan2
- NBEAL2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV52762332; called by muse, mutect2, varscan2
- NCKIPSD | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760490512, COSV53663164; called by muse, mutect2, varscan2
- NCOR1 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs781456795, COSV51991977; called by muse, mutect2, varscan2
- NDUFA8 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763028715, COSV65653608; called by muse, mutect2, varscan2
- NEK11 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV67285240; called by muse, mutect2, varscan2
- NELFB | c.1351T>C p.Y451H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.712); catalogued as COSV58026226; called by muse, mutect2, varscan2
- NELL1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV54314598; called by muse, mutect2, varscan2
- NFASC | c.2053G>A p.V685I (on ENST00000339876 / NM_001378329.1; = p.V681I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs771862901, COSV58357612; called by muse, mutect2, varscan2
- NFE2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56456916; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 28/172 reads (16%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX2-3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV60729246; called by muse, mutect2, varscan2
- NLGN4Y | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59299187; called by mutect2, varscan2
- NLRP1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 37/198 reads (19%) | catalogued as rs758319723, COSV52564949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP13 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.63); catalogued as rs571828268, COSV100738074, COSV61622951, COSV61623773; called by muse, mutect2, varscan2
- NLRP8 | c.2812G>T p.D938Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52592756, COSV52593228; called by muse, mutect2, varscan2
- NLRX1 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV52708691; called by muse, mutect2, varscan2
- NOM1 | c.628A>G p.S210G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51982138; called by muse, mutect2, varscan2
- NOTUM | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV68826594; called by muse, mutect2, varscan2
- NOX4 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54462667; called by muse, mutect2, varscan2
- NPAS2 | c.1841T>C p.M614T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV59561457; called by muse, mutect2, varscan2
- NPLOC4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as rs1378278966, COSV58618874; called by muse, mutect2, varscan2
- NR1H3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68008787; called by muse, mutect2, varscan2
- NRF1 | c.920T>A p.V307D | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56215879; called by muse, mutect2, varscan2
- NRG3 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100932472, COSV64580292; called by muse, mutect2
- NRXN1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs202244228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN3 | c.724G>C p.A242P (on ENST00000557594 / NM_001272020.2; = p.A874P on NM_004796.6) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55349100; called by muse, mutect2, varscan2
- NSG1 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs939101251, COSV67574934; called by muse, mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | catalogued as rs772197760; called by mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 36/231 reads (16%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUTM1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs746914938, COSV61548343; called by muse, mutect2, varscan2
- NUTM2A | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV67742146; called by muse, mutect2, varscan2
- NXPE3 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139135706; called by mutect2, varscan2
- OBSCN | c.18676C>T p.R6226* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs376526801; called by muse, mutect2, varscan2
- OGDHL | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200530979, COSV65104219; called by muse, mutect2, varscan2
- OPRM1 | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1406848349, COSV100001295; called by muse, mutect2, varscan2
- OR10H1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV58472739; called by muse, mutect2, varscan2
- OR10V1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.524); catalogued as rs774029687, COSV55700604; called by muse, mutect2, varscan2
- OR1K1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs766612245, COSV52957210; called by muse, mutect2, varscan2
- OR4B1 | c.559T>C p.C187R | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145940486; called by muse, mutect2, varscan2
- OR4C15 | c.505A>G p.T169A (on ENST00000314644; = p.T115A on NM_001001920.2) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV58955103; called by muse, mutect2, varscan2
- OR51B5 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760899084, COSV56175716, COSV56177519; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52R1 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1256259002, COSV61888565, COSV61889247; called by muse, mutect2, varscan2
- OR5T3 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV100282683, COSV57382262; called by muse, mutect2, varscan2
- ORC1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1407195060, COSV65364997; called by muse, mutect2
- OTOP2 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 58/517 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58883409; called by muse, mutect2, varscan2
- OTUD7B | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV64917592; called by muse, mutect2, varscan2
- P2RY13 | c.702del p.V235Yfs*81 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs771457469; called by mutect2, pindel, varscan2
- PACSIN2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1480334213, COSV54319085; called by mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 28/179 reads (16%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PCBP2 | c.524del p.P175Rfs*4 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs776329515; called by mutect2, pindel, varscan2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDHA12 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); catalogued as COSV56519282; called by muse, mutect2, varscan2
- PCDHA12 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.37); catalogued as COSV56496084; called by muse, mutect2, varscan2
- PCDHA2 | c.881C>G p.T294S | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.013); catalogued as COSV65370523; called by muse, mutect2, varscan2
- PCDHA4 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); catalogued as rs1441304336, COSV63542097; called by muse, mutect2, varscan2
- PCDHA5 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV65349470; called by muse, varscan2
- PCDHAC1 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs386352346, COSV53863427, COSV53873987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB2 | c.2009A>G p.Q670R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as COSV50619823; called by muse, varscan2
- PCDHB5 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782233245, COSV50655635; called by muse, mutect2, varscan2
- PCDHGA11 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54015359; called by muse, mutect2
- PCDHGA3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as rs1267309332, COSV54015321; called by muse, mutect2, varscan2
- PCDHGA5 | c.1014G>T p.Q338H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV54015336; called by muse, mutect2, varscan2
- PCID2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1404369378, COSV55814889; called by muse, mutect2, varscan2
- PCLO | c.10340C>T p.T3447M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs942302843, COSV61660184; called by muse, mutect2, varscan2
- PCNX2 | c.5609G>A p.R1870Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.64); catalogued as rs766878027, COSV99267156; called by muse, mutect2, varscan2
- PCSK2 | c.125del p.G42Efs*54 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as COSV99360859; called by mutect2, pindel, varscan2
- PCSK9 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs72658890, COSV100135639; called by muse, mutect2, varscan2
- PDGFRA | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV57265908, COSV57272418; called by muse, mutect2, varscan2
- PFDN5 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54476877; called by muse, mutect2, varscan2
- PGAP2 | c.4T>C p.Y2H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.592); catalogued as rs758096630, COSV53466880; called by muse, mutect2, varscan2
- PGGT1B | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV56974935; called by muse, mutect2, varscan2
- PGLYRP1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV50517426; called by muse, mutect2, varscan2
- PGM2L1 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV53349100; called by muse, mutect2, varscan2
- PHC3 | c.131G>A p.R44Q (on ENST00000494943 / NM_001308116.2; = p.R56Q on NM_024947.4) | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV71923725; called by muse, mutect2, varscan2
- PHTF2 | c.1679G>A p.R560H (on ENST00000248550 / NM_001366089.1; = p.R522H on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1217745366, COSV50337573; called by muse, mutect2, varscan2
- PI4KA | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV55420692; called by muse, mutect2
- PIAS2 | c.1759A>G p.S587G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.076); catalogued as rs771359312, COSV67094776; called by muse, mutect2, varscan2
- PIGK | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565004204, COSV63062156; called by muse, mutect2, varscan2
- PIGU | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1391972606, COSV54165705, COSV99466600; called by muse, mutect2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 16/94 reads (17%) | catalogued as rs749506841; called by mutect2, varscan2
- PITPNM3 | c.2016C>G p.I672M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV52593648, COSV52599130; called by muse, mutect2, varscan2
- PKHD1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772402137, COSV61873723; called by muse, mutect2, varscan2
- PLEC | c.6259C>T p.R2087C (on ENST00000322810 / NM_201380.4; = p.R1977C on NM_000445.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs566539439, COSV100510382; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHH2 | c.3585G>T p.Q1195H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56759881; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs765091847; called by mutect2, varscan2
- PNMA1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754458974, COSV54098142; called by muse, mutect2, varscan2
- PNMT | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs768713506, COSV54093938; called by muse, mutect2, varscan2
- PNPLA7 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53005396; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.662C>T p.T221I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV57968102; called by muse, mutect2, varscan2
- POLE2 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs758265986, COSV53560202, COSV53560375; called by muse, mutect2, varscan2
- POLH | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs538518658, COSV64779660; called by muse, mutect2, varscan2
- POLQ | c.6838A>G p.M2280V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51759562; called by muse, mutect2, varscan2
- POLR1G | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV50005217; called by muse, mutect2, varscan2
- POLRMT | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as rs1352517780, COSV52114793; called by mutect2, varscan2
- POT1 | c.1559A>G p.D520G | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1370868219, COSV62933884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs143142906; called by muse, mutect2, varscan2
- PPHLN1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56735657; called by muse, mutect2, varscan2
- PPL | c.1362dup p.T455Hfs*4 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | catalogued as rs753902804; called by mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP1R12B | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61122677; called by muse, mutect2, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 29/159 reads (18%) | catalogued as rs758922105; called by mutect2, pindel, varscan2
- PPP1R16B | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV55383346; called by muse, mutect2, varscan2
- PPP1R9A | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56880421; called by mutect2, varscan2
- PPP6C | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs144776498; called by muse, mutect2, varscan2
- PPT1 | c.323A>G p.Y108C (on ENST00000433473; = p.Y109C on NM_000310.4) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1228395356, COSV65656064; called by muse, varscan2
- PRAMEF12 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs760897801, COSV63216381; called by muse, mutect2, varscan2
- PRAMEF14 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs75542004; called by muse, mutect2, varscan2
- PRCC | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV54858183; called by muse, mutect2
- PRDM5 | c.1139T>G p.L380R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV53359873; called by muse, mutect2
- PREX1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV64255900; called by muse, mutect2, varscan2
- PRKAR1B | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1340953562, COSV64318822, COSV64319752; called by muse, mutect2, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | catalogued as rs764069617; called by mutect2, pindel, varscan2
- PRKAR2A | c.1077C>A p.C359* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV55553903; called by muse, mutect2, varscan2
- PRKCD | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV57850897; called by muse, mutect2
- PRKRIP1 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs781823557, COSV61350618; called by muse, mutect2, varscan2
- PRORP | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV51617400, COSV51622495; called by muse, mutect2, varscan2
- PRPF8 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 113/421 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV59266995; called by muse, mutect2, varscan2
- PRSS16 | c.284T>G p.I95R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV57916644; called by muse, mutect2, varscan2
- PRUNE2 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs370383759; called by muse, mutect2
- PSD | c.1454A>G p.E485G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV50056681; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV99194092; called by mutect2, varscan2
- PSMB8 | c.31dup p.R11Pfs*58 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as rs775701157; called by mutect2, pindel
- PSME1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV52825698; called by muse, mutect2, varscan2
- PTGER3 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV100138422, COSV60696796; called by muse, mutect2, varscan2
- PTGS1 | c.381del p.T128Pfs*17 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as rs779702921; called by mutect2, pindel, varscan2
- PTK2B | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs923237640, COSV57764471; called by muse, mutect2, varscan2
- PTPN21 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV60851376; called by muse, mutect2, varscan2
- PTPN21 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1012930448, COSV60850026, COSV60851386; called by muse, mutect2
- PTPRA | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53780898; called by muse, mutect2, varscan2
- PTPRE | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs775855765, COSV54557601; called by muse, mutect2, varscan2
- PTPRF | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771288963, COSV63448247; called by muse, mutect2, varscan2
- PTPRJ | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV69254168; called by muse, mutect2, varscan2
- PTPRM | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs148967648; called by muse, mutect2, varscan2
- PTPRM | c.2642G>T p.R881L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59877749; called by mutect2, varscan2
- PTPRU | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV60535166; called by muse, mutect2, varscan2
- PTRHD1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1238843879, COSV53230088; called by muse, mutect2, varscan2
- PXDN | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs781527729, COSV53231725; called by muse, mutect2, varscan2
- PXDNL | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62496716; called by muse, mutect2
- PYDC1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57252103; called by muse, mutect2, varscan2
- PYGL | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.251); catalogued as COSV53588270; called by muse, mutect2
- QSER1 | c.2279C>T p.P760L (on ENST00000399302; = p.P889L on NM_001076786.3) | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs866257927, COSV67901573; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB10 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs758990324, COSV53092450; called by muse, mutect2, varscan2
- RAB6C | c.467G>T p.R156M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as COSV101308503; called by muse, mutect2, varscan2
- RACGAP1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1272653493, COSV56699053; called by muse, mutect2, varscan2
- RAF1 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs730880382, COSV52579905, COSV52583001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAI1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs928593627, COSV55389960; called by muse, mutect2, varscan2
- RANBP3 | c.1443G>T p.E481D (on ENST00000340578 / NM_007322.3; = p.E476D on NM_003624.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV50385275; called by muse, mutect2, varscan2
- RAPGEF1 | c.3067C>T p.R1023C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775152902, COSV64697669; called by muse, mutect2, varscan2
- RAPGEF2 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as rs768712188, COSV100031022, COSV52426064; called by muse, mutect2, varscan2
- RASEF | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764188878, COSV64588397; called by muse, mutect2, varscan2
- RASSF7 | c.123A>G p.I41M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV60348310; called by muse, mutect2
- RAVER2 | c.1412-1G>A p.X471_splice (on ENST00000294428 / NM_001366165.1; = p.X458_splice on NM_018211.4) | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53810387, COSV99605204; called by muse, mutect2, varscan2
- RBL1 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV60333045; called by muse, mutect2, varscan2
- RBM12 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV58292513; called by muse, mutect2, varscan2
- RBP3 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs782553847; called by muse, mutect2, varscan2
- RDH13 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781132193, COSV52562501; called by muse, mutect2
- RECQL4 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372741479; ClinVar: uncertain significance; called by muse, mutect2
- REEP4 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 68/710 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57942873; called by muse, mutect2
- RELN | c.7904C>T p.A2635V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs759387967, COSV59029263; called by muse, mutect2, varscan2
- RFX3 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56523611; called by muse, mutect2, varscan2
- RFX5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1260985647, COSV51840266; called by muse, mutect2, varscan2
- RGS4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63358048; called by muse, mutect2
- RHOG | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs770897526, COSV53466891; called by muse, mutect2, varscan2
- RIMS4 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65720594; called by muse, mutect2, varscan2
- RLF | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV65652954; called by muse, mutect2, varscan2
- RNASE9 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100141199, COSV100141230; called by muse, mutect2, varscan2
- RNF169 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs1257811850, COSV55135182; called by muse, mutect2, varscan2
- RNF213 | c.15445G>A p.E5149K | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.083); catalogued as rs367820011; called by muse, mutect2, varscan2
- RNF31 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs761613885, COSV60728255; called by muse, mutect2, varscan2
- RNF40 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs1213192029, COSV52697269, COSV99354633; called by muse, mutect2, varscan2
- ROCK2 | c.4046C>A p.P1349H | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59963624; called by muse, mutect2, varscan2
- ROCK2 | c.800del p.G267Vfs*14 | Frame Shift Del (DEL) | VAF 44/256 reads (17%) | catalogued as COSV55087270; called by mutect2, pindel, varscan2
- RORB | c.142A>C p.S48R (on ENST00000396204 / NM_001365023.1; = p.S37R on NM_006914.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65339323; called by muse, mutect2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs781249059; called by mutect2, pindel, varscan2
- RP1 | c.2675C>A p.A892E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1395156809, COSV55121233, COSV55124738; called by muse, mutect2
- RPE | c.500T>C p.F167S (on ENST00000359429 / NM_001318926.1; = p.F117S on NM_006916.2) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV55996443; called by muse, mutect2, varscan2
- RPGRIP1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV52855878; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP25L | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753365809, COSV52407593; called by muse, mutect2, varscan2
- RSPH9 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs888702543, COSV64665680; called by muse, mutect2, varscan2
- RTL4 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs368859857, COSV61207215; called by muse, mutect2, varscan2
- RUSC2 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV63430106; called by muse, mutect2, varscan2
- RUSC2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs377583326; called by muse, mutect2, varscan2
- RYR1 | c.685T>G p.C229G | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62108289; called by muse, mutect2, varscan2
- SAC3D1 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.258); catalogued as COSV57248343; called by muse, mutect2, varscan2
- SAMD15 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs974785526, COSV53627409; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as COSV59083791; called by mutect2, varscan2
- SASH1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs575597604, COSV66560399, COSV66560961; called by muse, mutect2, varscan2
- SASH3 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs758842379, COSV63556156; called by muse, mutect2, varscan2
- SBNO1 | c.425C>T p.A142V (on ENST00000420886; = p.A141V on NM_018183.5) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV57345043; called by muse, mutect2, varscan2
- SCAF4 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs752030908, COSV54585998; called by muse, mutect2, varscan2
- SCAP | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs761681586, COSV55563955; called by muse, mutect2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs760494753; called by mutect2, varscan2
- SCN1A | c.1322A>T p.E441V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57684140; called by muse, mutect2, varscan2
- SCN7A | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 27/191 reads (14%) | catalogued as COSV69270113; called by muse, mutect2, varscan2
- SCRIB | c.4127G>A p.R1376H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781874101, COSV57592454; called by muse, mutect2, varscan2
- SEC14L1 | c.1847_1849del p.E616del | In Frame Del (DEL) | VAF 40/189 reads (21%) | catalogued as rs1254019870; called by pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 33/66 reads (50%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3A | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | catalogued as COSV54869697, COSV54885264; called by muse, mutect2, varscan2
- SEMA3B | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100312793; called by muse, mutect2, varscan2
- SEMA6A | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as COSV56709362; called by muse, mutect2, varscan2
- SERPINE2 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as COSV51459667; called by muse, mutect2, varscan2
- SETBP1 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1380272330, COSV56327337, COSV56329995; called by muse, mutect2, varscan2
- SETBP1 | c.4005G>T p.M1335I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56334581; called by muse, varscan2
- SETD1A | c.4330C>T p.R1444W | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750790917, COSV52691701; called by muse, mutect2, varscan2
- SETD4 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1459319214, COSV100145620; called by mutect2, varscan2
- SF1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as rs149376410; called by muse, mutect2, varscan2
- SFRP2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as COSV56837491; called by muse, mutect2
- SGO1 | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV55424879; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 31/116 reads (27%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGSM2 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs61733094, COSV52161058; called by muse, mutect2, varscan2
- SHF | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372948670; called by muse, mutect2, varscan2
- SHROOM1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60582155, COSV60582245; called by muse, mutect2, varscan2
- SIDT2 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs774010573, COSV54060125; called by muse, mutect2, varscan2
- SIGLEC1 | c.5047G>A p.A1683T | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52470828; called by muse, mutect2, varscan2
- SIGLEC6 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); catalogued as rs367569452; called by muse, mutect2, varscan2
- SIGLEC7 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58315274; called by muse, mutect2, varscan2
- SIX2 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100284189; called by muse, mutect2, varscan2
- SKI | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66014499; called by muse, mutect2
- SLC15A2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55198482, COSV55200380; called by muse, mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC17A7 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55549614, COSV55549814; called by muse, mutect2, varscan2
- SLC27A4 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55961515; called by muse, mutect2, varscan2
- SLC30A9 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs772621304, COSV52558758; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC39A1 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1414107964, COSV57845319; called by muse, mutect2, varscan2
- SLC39A3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs775552929, COSV54118817; called by muse, mutect2, varscan2
- SLC3A1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as rs753527558, COSV53224516; called by muse, mutect2, varscan2
- SLC4A11 | c.2413G>A p.V805M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.05); catalogued as rs145325200, COSV66260872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A3 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.98); catalogued as rs1460553454, COSV56095901; called by muse, mutect2, varscan2
- SLC6A18 | c.621+2T>C p.X207_splice | Splice Site (SNP) | VAF 20/203 reads (10%) | catalogued as COSV57253933; called by muse, mutect2, varscan2
- SLC6A20 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.98); PolyPhen probably damaging (1); catalogued as rs781203780, COSV62072440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC7A3 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as rs762268790, COSV53227747; called by muse, mutect2, varscan2
- SLC9A1 | c.2360G>T p.S787I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV56056022; called by muse, mutect2
- SLC9C2 | c.900T>C p.T300= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV62947453, COSV62948693; called by mutect2, varscan2
- SLCO1C1 | c.1233del p.I412* | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | catalogued as rs766878114, COSV56867969; called by mutect2, pindel, varscan2
- SLFN5 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV55483141; called by muse, mutect2, varscan2
- SLIT1 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs759345991, COSV56587537, COSV56597313; called by muse, mutect2, varscan2
- SLITRK5 | c.1260C>A p.Y420* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV61525605; called by mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SLX4 | c.2809G>T p.G937W | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53567750; called by muse, mutect2, varscan2
- SMAD9 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs759141619, COSV63206125; called by mutect2, varscan2
- SMARCA1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1342799293, COSV64411153; called by muse, mutect2, varscan2
- SMARCC2 | c.2703C>G p.I901M | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV57222086; called by muse, mutect2, varscan2
- SMARCC2 | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.403); catalogued as COSV57223906; called by muse, mutect2
- SMC1B | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs754914778, COSV62532963; called by muse, mutect2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs760667210; called by mutect2, varscan2
- SNRNP200 | c.5725C>T p.Q1909* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV55531486; called by muse, mutect2, varscan2
- SNRPC | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55075921, COSV55076226; called by muse, mutect2, varscan2
- SOAT1 | c.1072A>C p.S358R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62656492; called by muse, mutect2, varscan2
- SPARCL1 | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56805848; called by muse, mutect2, varscan2
- SPATA5 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs764600164, COSV56782773; called by muse, mutect2, varscan2
- SPECC1 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54966611; called by muse, mutect2, varscan2
- SPECC1 | c.2264A>T p.E755V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54966623; called by muse, mutect2, varscan2
- SPINK13 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs374053619; called by muse, mutect2, varscan2
- SPINT2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs576047179, COSV56648849; called by muse, mutect2, varscan2
- SPPL2B | c.1278G>A p.G426= | Splice Region (SNP) | VAF 12/69 reads (17%) | catalogued as rs946471551, COSV66317343; called by muse, mutect2, varscan2
- SPRED2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs780902942, COSV62695413; called by muse, mutect2, varscan2
690 further variants in this file (351 protein-altering or splice-affecting, 311 silent, 28 other) are not listed here.
